Gene-level copy-number profile of tumor specimen TCGA-B6-A3ZX-01A from TCGA case TCGA-B6-A3ZX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.5 years (18,434 days).
Specimen TCGA-B6-A3ZX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4104df00-1af0-40be-867d-ba794e075ae7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A3ZX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c102fdc-ef66-44be-b030-ff326d690d46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,802; copy number 2: 36,245; copy number 3: 7,797; copy number 4: 2,332; copy number 5: 1,136; copy number 6: 323; copy number 7: 144; copy number 8: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A3ZX-01A-11D-A238-01): tumor purity 0.13, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,240 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–26,013,025, 416 genes, copy number 5 (broad region; genes not listed).
- chr7:18,948,898–34,156,427, 294 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:99,013,266–109,345,954, 180 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr8:109,899,246–111,236,203, 14 genes, copy number 8: AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37.
- chr8:111,380,603–111,380,868, 1 gene, copy number 8: SERPINA15P.
- chr13:92,446,470–114,337,626, 332 genes, copy number 5–6 (broad region; genes not listed).
- chr15:89,760,591–89,815,401, 2 genes, copy number 7 (within-gene range 2–7): MESP2, ANPEP.
- chr15:89,850,637–89,850,721, 1 gene, copy number 7: MIR5094.

Autosomal genes at a single copy (total copy number 1): 11,802. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
